Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A7CJ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A7CJ-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT - CONSULT

Patient Name: [REDACTED]
Address: [REDACTED]
Gender: F
DOB: [REDACTED] (Age: [REDACTED])
Physician(s): [REDACTED], M.D.

Service: [REDACTED]
Location: [REDACTED]
MRN: [REDACTED]
Hospital #: [REDACTED]
Patient Type: [REDACTED]

Accession #: [REDACTED]
Received: [REDACTED]
Reported: [REDACTED]

DIAGNOSIS

UTERUS, CERVIX, BIOPSY

- MODERATELY DIFFERENTIATED INVASIVE SQUAMOUS CELL CARCINOMA, KERATINIZING TYPE
- FOCAL LYMPHVASCULAR SPACE INVASION IS IDENTIFIED
- SEVERE DYSPLASIA (CIN 3)

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

[REDACTED] M.D.

Report Electronically Reviewed and Signed Out By [REDACTED] M.D.

Microscopic Description and Comment

Histologic sections show invasive, moderately differentiated keratinizing squamous cell carcinoma. Focal lymphovascular space invasion is identified. The tumor extends to the edges of the unlinked tissue pieces. Severe dysplasia (CIN 3) is also identified. ([REDACTED])

History

The patient is a [REDACTED] year old woman with a history of cervical bleeding.

Material(s) Received

Received are three slides labeled [REDACTED] and sublabelled A through C. These are derived from cervical biopsies performed on [REDACTED] as detailed in the accompanying surgical pathology report. Slide A represents the frozen section remnant. The material originates from [REDACTED]

*ICD O-3
Carcinoma, squamous cell keratinizing NOS 8071/3
Site Cervix NOS C53.9
9/25/13*

Physician Copy - [REDACTED]
END OF REPORT

Page 1 of 1

HPVAA Discrepancy		X

Source: NCI Genomic Data Commons file f68d3b96-3fcd-4cf6-9e2f-d0b0ccf34e06 (TCGA-C5-A7CJ.3EA65A3A-81EC-4121-AFA9-620B37BB23A8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).